Somatic mutation profile of tumor specimen TCGA-HD-A634-01A (aliquot TCGA-HD-A634-01A-11D-A28R-08) from TCGA case TCGA-HD-A634, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 57.0 years (20,810 days).
Specimen TCGA-HD-A634-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 291a9ef8-06d2-4641-9139-98a574d030a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-A634-10A (Blood Derived Normal), aliquot TCGA-HD-A634-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f305fd17-07f1-4fb3-aa49-1fd34d0c7d92

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 14, Frame Shift Del 5, Nonsense Mutation 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK2 | c.2519C>T p.T840M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1390793752, COSV64492138; called by muse, mutect2, varscan2
- ANKS1A | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.952); catalogued as COSV100832722; called by muse, mutect2, varscan2
- BANK1 | c.2029C>A p.Q677K | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100536675; called by muse, mutect2, varscan2
- CALCRL | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV101131019; called by muse, mutect2, varscan2
- CAMK2A | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV100652084; called by muse, mutect2, varscan2
- CSRNP3 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100086138; called by muse, mutect2, varscan2
- FOXJ3 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100692102; called by muse, mutect2, varscan2
- FRG1 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs766767633, COSV99903610; called by muse, mutect2, varscan2
- GRID2 | c.1778del p.P593Hfs*8 | Frame Shift Del (DEL) | VAF 36/119 reads (30%) | catalogued as COSV56182235; called by mutect2, pindel, varscan2
- H2BU1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.308); catalogued as rs562887286, COSV100797306, COSV64209949; called by muse, mutect2, varscan2
- HEPACAM | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324733953, COSV53429603; called by muse, mutect2, varscan2
- KLHL34 | c.634C>A p.R212S | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.7); catalogued as COSV101069973, COSV65279951; called by muse, mutect2, varscan2
- LRP1B | c.12044G>T p.G4015V | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101259159, COSV67227651; called by muse, mutect2, varscan2
- MARF1 | c.4712C>A p.S1571Y | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100706178; called by muse, mutect2
- OR13G1 | c.643T>A p.Y215N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100687481; called by muse, mutect2, varscan2
- PCDHGA11 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); catalogued as rs1287891140, COSV99543596; called by muse, mutect2, varscan2
- SEMA3C | c.986+1G>T p.X329_splice | Splice Site (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99543553; called by muse, mutect2, varscan2
- SERPINC1 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100875103; called by muse, mutect2, varscan2
- SSUH2 | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100436052; called by muse, mutect2, varscan2
- TMEM132A | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 115/269 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV50004279; called by muse, mutect2, varscan2
- TRPM2 | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs145895219; called by muse, mutect2, varscan2
- UBE2Q1 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99427591; called by muse, mutect2, varscan2
- VPS8 | c.1672G>A p.D558N (on ENST00000625842 / NM_001349294.1; = p.D556N on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV99803295; called by muse, varscan2
- ZFHX3 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344399327, COSV51719754; called by muse, mutect2, varscan2
- ZNF598 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs373524057; called by muse, varscan2
- ZNF98 | c.29T>C p.M10T | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1449287491, COSV100757566; called by muse, mutect2, varscan2
- CCNF | c.64del p.R22Efs*2 | Frame Shift Del (DEL) | VAF 39/129 reads (30%) | called by mutect2, pindel, varscan2
- CLINT1 | c.1417_1421del p.P474Yfs*4 | Frame Shift Del (DEL) | VAF 59/154 reads (38%) | called by mutect2, pindel, varscan2
- KMT2C | c.4111G>C p.D1371H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- PLA2G4A | c.17del p.P6Lfs*6 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- USP9X | c.4674del p.L1559* | Frame Shift Del (DEL) | VAF 44/68 reads (65%) | called by mutect2, pindel, varscan2
- CCDC106 | c.288C>T p.F96= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs545356408, COSV99553229; called by muse, mutect2, varscan2
- DEF8 | c.870G>A p.V290= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs1286180418, COSV99240681; called by muse, mutect2, varscan2
- HRH3 | c.891C>T p.G297= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as rs772752067, COSV100420684; called by muse, varscan2
- KNDC1 | c.3243C>T p.P1081= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs550328756, COSV100465822; called by muse, mutect2, varscan2
- MARF1 | c.4710C>A p.L1570= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV100706179; called by muse, mutect2
- MDC1 | c.3141C>T p.A1047= | Silent (SNP) | VAF 64/147 reads (44%) | catalogued as COSV100903012; called by muse, mutect2, varscan2
- MFSD2A | c.81G>T p.P27= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100861726; called by muse, mutect2, varscan2
- PCDHGA4 | c.1779C>A p.I593= | Silent (SNP) | VAF 130/386 reads (34%) | catalogued as COSV53979050, COSV99543592; called by muse, mutect2, varscan2
- RBPJL | c.102C>T p.D34= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as rs533358769, COSV59212560; called by muse, mutect2, varscan2
- ROCK1 | c.3177G>A p.L1059= | Silent (SNP) | VAF 92/294 reads (31%) | catalogued as COSV67696042; called by muse, mutect2, varscan2
- SMC1A | c.2745T>C p.I915= | Silent (SNP) | VAF 70/77 reads (91%) | catalogued as COSV100447614; called by muse, mutect2, varscan2
- SUSD4 | c.1245C>T p.P415= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs761134277, COSV100663871; called by muse, mutect2, varscan2
- TMTC4 | c.69G>A p.K23= (on ENST00000376234 / NM_001350577.2; = p.K42= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100168827; called by muse, mutect2, varscan2
- USH2A | c.5052G>A p.P1684= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs747119023, COSV56405628; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845920 ins C | 5'Flank (INS) | VAF 68/207 reads (33%) | called by mutect2, pindel, varscan2
